Somatic mutation profile of tumor specimen TARGET-10-PASXIL-09A (aliquot TARGET-10-PASXIL-09A-01D) from TARGET case TARGET-10-PASXIL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.8 years (3,222 days).
Specimen TARGET-10-PASXIL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5250069f-e1f7-472b-8b70-306e3adba600.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASXIL-10A (Blood Derived Normal), aliquot TARGET-10-PASXIL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c300df12-55b9-4689-85ae-e1755335b6e2

The open-access MAF lists 30 somatic variants for this specimen: 26 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 2, Intron 2, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2B | c.157-5G>A | Splice Region (SNP) | VAF 26/87 reads (30%) | catalogued as rs768407545, COSV52804905; called by muse, mutect2, varscan2
- FAM114A2 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV104418339; called by muse, varscan2
- GDAP2 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV65613516; called by muse, mutect2, varscan2
- KLK15 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1326706289, COSV56825765; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- OPRK1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as rs200159306, COSV55568063; called by muse, mutect2, varscan2
- OTX2 | c.116G>T p.R39L (on ENST00000408990 / NM_172337.3; = p.R47L on NM_021728.4) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257927; called by muse, mutect2, varscan2
- PHF6 | c.123_124insGGTTCCGC p.H42Gfs*42 | Frame Shift Ins (INS) | VAF 30/41 reads (73%) | catalogued as COSV59699013, COSV59701670; called by pindel, varscan2
- RGS7 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs765729186, COSV58529676; called by muse, mutect2, varscan2
- SHANK2 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1387204530, COSV53584143; called by muse, mutect2, varscan2
- SUZ12 | c.689T>C p.L230P | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59497701; called by muse, mutect2, varscan2
- SUZ12 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 44/138 reads (32%) | catalogued as rs372162318, COSV59497708; called by muse, mutect2
- SYNE2 | c.5738T>A p.L1913H | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751620992, COSV59938572; called by muse, mutect2, varscan2
- TENM2 | c.4499G>A p.R1500H (on ENST00000518659 / NM_001122679.2; = p.R1261H on NM_001080428.3) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757391209, COSV69122198, COSV69137909; called by muse, mutect2, varscan2
- ZDBF2 | c.6704G>A p.R2235H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs751972875, COSV65621399; called by muse, mutect2, varscan2
- ZNF630 | c.1055G>T p.C352F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52094829; called by muse, mutect2, varscan2
- ADAMTS7 | c.2528G>T p.R843M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC180 | c.4498A>G p.R1500G | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- DHRS13 | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2
- GBP3 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- KCTD3 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.694); called by muse, varscan2
- KDM6A | c.3338_3345delinsG p.V1113Gfs*5 | Frame Shift Del (DEL) | VAF 28/30 reads (93%) | called by pindel, varscan2*
- RANBP10 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- STARD9 | c.5401C>A p.L1801M | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- VPS13B | c.5910C>A p.H1970Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); called by muse, mutect2
- MAGEB18 | c.960C>A p.A320= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- PLAGL1 | c.1140G>T p.L380= | Silent (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- GABRA5 | c.87-3171C>T | Intron (SNP) | VAF 54/113 reads (48%) | catalogued as rs972377171; called by muse, mutect2, varscan2
- MCOLN1 | c.985-23C>A | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as COSV51174468; called by mutect2, varscan2
